Somatic mutation profile of tumor specimen ALCH-B2EE-TTP1-A (aliquot ALCH-B2EE-TTP1-A-4-0-D-A777-36) from ALCHEMIST case ALCH-B2EE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.8 years (20,760 days).
Specimen ALCH-B2EE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b0bb090-0817-4cf3-9b10-ec073082d170.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2EE-NB1-A (Blood Derived Normal), aliquot ALCH-B2EE-NB1-A-2-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea7d2660-c18b-4e6b-b1de-87f52a692d5b

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 2 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Intron 6, Nonsense Mutation 4, Silent 2, RNA 1, Splice Site 1, 5'UTR 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 87/735 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTL9 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs781910740, COSV61006476; called by muse, mutect2, varscan2
- ADGRE1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as rs202045997; called by muse, mutect2, varscan2
- ANK2 | c.11694+1G>T p.X3898_splice | Splice Site (SNP) | VAF 79/549 reads (14%) | catalogued as rs1398611672; called by muse, mutect2, varscan2
- AOAH | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772606211, COSV51737318, COSV51751730; called by muse, mutect2, varscan2
- BICD1 | c.603T>G p.H201Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV55679650; called by mutect2, varscan2
- CHD9 | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs759676826; called by muse, mutect2, varscan2
- COL20A1 | c.1191G>T p.W397C | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316726667, COSV58912115; called by muse, mutect2, varscan2
- CXCR2 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768791823, COSV59280832; called by muse, mutect2, varscan2
- GAB4 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs779967778, COSV68752811; called by muse, varscan2
- MYO18B | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 49/417 reads (12%) | catalogued as COSV100125550; called by muse, mutect2, varscan2
- NCOA2 | c.2042C>T p.T681I | Missense Mutation (SNP) | VAF 35/275 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs370409922; called by muse, mutect2, varscan2
- PCDHA4 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); catalogued as COSV63542909; called by muse, mutect2, varscan2
- PLA2G4E | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 28/247 reads (11%) | catalogued as rs775743438, COSV68152161; called by muse, varscan2
- TSKS | c.1237G>T p.G413W | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55873344; called by muse, mutect2, varscan2
- UBE2O | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1318859888; called by muse, mutect2, varscan2
- VARS1 | c.3364C>T p.R1122W | Missense Mutation (SNP) | VAF 30/502 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs138566905; called by muse, mutect2
- ADGRD1 | c.2109T>A p.N703K | Missense Mutation (SNP) | VAF 61/488 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ASCC2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2
- DHRS1 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 77/639 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ETFA | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 99/748 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRE | c.265G>C p.G89R | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GPR50 | c.959C>A p.S320Y | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- HOXA11 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 88/558 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- LYST | c.6877C>G p.H2293D | Missense Mutation (SNP) | VAF 64/352 reads (18%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- OLFM3 | c.910T>C p.F304L (on ENST00000338858 / NM_001288821.1; = p.F284L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PCDH11X | c.1204C>A p.H402N | Missense Mutation (SNP) | VAF 74/609 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPIP5K1 | c.3895A>G p.T1299A (on ENST00000396923; = p.T1274A on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRR23A | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2
- RAB1B | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- SCRIB | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 36/337 reads (11%) | called by muse, mutect2, varscan2
- SULF1 | c.508A>T p.N170Y | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, varscan2
- TENM1 | c.4510C>T p.P1504S | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- WDR81 | c.4444C>G p.L1482V (on ENST00000409644 / NM_001163809.2; = p.L431V on NM_152348.4) | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF536 | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 59/386 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- A2M | c.1779C>T p.S593= | Silent (SNP) | VAF 70/593 reads (12%) | catalogued as rs868449593, COSV59386462; called by muse, mutect2, varscan2
- COL12A1 | c.7476C>T p.I2492= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs895079123, COSV59398182; called by muse, varscan2
- AP000769.3 | chr11:65503013 del CTACATTAATCCTGGAATAAAAG | 5'Flank (DEL) | VAF 38/180 reads (21%) | called by mutect2, pindel
- ENY2 | c.229+13G>A | Intron (SNP) | VAF 30/229 reads (13%) | called by muse, mutect2, varscan2
- EYA1 | c.33+64842G>A | Intron (SNP) | VAF 60/470 reads (13%) | catalogued as rs746020717; called by muse, varscan2
- GDI1 | c.389-215C>T | Intron (SNP) | VAF 58/619 reads (9%) | called by muse, mutect2
- NEU3 | c.307-1082A>G | Intron (SNP) | VAF 15/316 reads (5%) | called by muse, mutect2
- R3HDM2 | c.*446A>G | 3'UTR (SNP) | VAF 8/102 reads (8%) | catalogued as rs1453353142; called by muse, mutect2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 16/314 reads (5%) | catalogued as rs910081914; called by muse, mutect2
- SDHAP1 | n.2104G>A | RNA (SNP) | VAF 80/1204 reads (7%) | called by muse, mutect2
- WDR17 | c.-13G>A | 5'UTR (SNP) | VAF 22/109 reads (20%) | called by muse, mutect2, varscan2
- YDJC | c.424+48G>C | Intron (SNP) | VAF 72/486 reads (15%) | called by muse, mutect2, varscan2
